Somatic mutation profile of tumor specimen C3N-02030-01 (aliquot CPT0133760078) from CPTAC case C3N-02030, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 62.7 years (22,893 days).
Specimen C3N-02030-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4cffa1e-227f-485b-8cd4-2d2f29c76e17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02030-71 (Blood Derived Normal), aliquot CPT0133880002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ed6c434-04d0-49c1-aef9-e6f3c645b188

The open-access MAF lists 646 somatic variants for this specimen: 446 protein-altering or splice-affecting, 120 silent, 80 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 299, Silent 120, Frame Shift Del 82, Intron 51, Frame Shift Ins 28, Nonsense Mutation 22, 3'UTR 10, 5'UTR 6, RNA 6, Splice Region 5, Splice Site 5, 5'Flank 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 106/291 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 54/99 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FOXG1 | c.506dup p.K170Qfs*285 | Frame Shift Ins (INS) | VAF 26/237 reads (11%) | catalogued as rs1452295073; ClinVar: pathogenic; called by mutect2, pindel
- GRM1 | c.26dup p.A11Sfs*78 | Frame Shift Ins (INS) | VAF 129/422 reads (31%) | catalogued as rs758809498; ClinVar: pathogenic; called by mutect2, varscan2
- PARK7 | c.189del p.E64Rfs*25 | Frame Shift Del (DEL) | VAF 98/348 reads (28%) | catalogued as rs759703272; ClinVar: likely pathogenic; called by mutect2, varscan2
- PRPF6 | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 107/284 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs387907100, CM112959, COSV53868700; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.103A>G p.M35V | Missense Mutation (SNP) | VAF 33/98 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs876659443, CM110119, COSV64289131, COSV64291926, COSV64310633; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 101/235 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TECTA | c.5977C>T p.R1993* | Nonsense Mutation (SNP) | VAF 85/221 reads (38%) | catalogued as rs760574657; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USP9X | c.2224C>T p.R742* | Nonsense Mutation (SNP) | VAF 25/76 reads (33%) | catalogued as rs1555924860, COSV100199662; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.4036G>A p.V1346M | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs767871494, COSV52201017; called by muse, mutect2, varscan2
- ABCB9 | c.1672del p.L558Wfs*24 (on ENST00000280560 / NM_019625.4; = p.L515Wfs*24 on NM_019624.3) | Frame Shift Del (DEL) | VAF 63/195 reads (32%) | catalogued as rs1334723787; called by mutect2, pindel, varscan2
- ABCC1 | c.2656G>A p.V886I | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs756648375; called by muse, mutect2, varscan2
- ABI3 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs770714352; called by muse, mutect2, varscan2
- ACTN4 | c.2021G>A p.R674H | Missense Mutation (SNP) | VAF 43/275 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs758778538; called by muse, mutect2, varscan2
- ADAMTS16 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 72/207 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1484616740, COSV56997505; called by muse, mutect2, varscan2
- AGO2 | c.1806del p.A603Pfs*92 | Frame Shift Del (DEL) | VAF 196/315 reads (62%) | catalogued as rs748399150; called by mutect2, pindel, varscan2
- AKAP8 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs537526016; called by muse, mutect2, varscan2
- AKAP9 | c.116dup p.R40Efs*7 | Frame Shift Ins (INS) | VAF 47/124 reads (38%) | catalogued as rs765201611; called by mutect2, varscan2
- ALDH7A1 | c.1061A>T p.Y354F | Missense Mutation (SNP) | VAF 78/248 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as CM121731; called by muse, mutect2, varscan2
- ALG5 | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53504362; called by muse, mutect2, varscan2
- AMER1 | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 10/207 reads (5%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as COSV57654677; called by muse, mutect2
- AOX1 | c.1666C>A p.L556I | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs769661664; called by muse, mutect2, varscan2
- APOA5 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 212/595 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM120394; called by muse, mutect2, varscan2
- ATP2B3 | c.2132C>T p.T711M | Missense Mutation (SNP) | VAF 141/347 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99051133; called by muse, mutect2, varscan2
- AZU1 | c.483del p.R162Vfs*11 | Frame Shift Del (DEL) | VAF 58/177 reads (33%) | catalogued as rs772652509, COSV99297150; called by mutect2, pindel, varscan2
- B3GAT1 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs763308287; called by muse, mutect2, varscan2
- BMPR1B | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373000965; called by muse, mutect2, varscan2
- BRD2 | c.1932C>A p.Y644* | Nonsense Mutation (SNP) | VAF 101/308 reads (33%) | catalogued as COSV100875888; called by muse, mutect2, varscan2
- CACNB1 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs753711036; called by muse, mutect2, varscan2
- CACYBP | c.432del p.V145Sfs*22 | Frame Shift Del (DEL) | VAF 12/67 reads (18%) | catalogued as rs1161545619; called by mutect2, pindel, varscan2
- CALHM1 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 64/668 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs373850573; called by muse, mutect2
- CCDC190 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 79/341 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs373634463; called by muse, mutect2, varscan2
- CEBPA | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 244/621 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781549846; called by muse, mutect2, varscan2
- CERT1 | c.1402-3del | Splice Region (DEL) | VAF 18/49 reads (37%) | catalogued as rs768479535; called by mutect2, pindel, varscan2
- CLDN12 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 119/371 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.192); catalogued as COSV55307631; called by muse, mutect2, varscan2
- COL14A1 | c.1321+1G>A p.X441_splice | Splice Site (SNP) | VAF 25/73 reads (34%) | catalogued as rs775204866, COSV52852671; called by muse, mutect2, varscan2
- COL27A1 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs781277879, COSV61925278; called by muse, mutect2, varscan2
- COL7A1 | c.2377C>T p.R793W | Missense Mutation (SNP) | VAF 174/495 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778104401; called by muse, mutect2, varscan2
- COL8A1 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs558799692; called by muse, mutect2, varscan2
- CPAMD8 | c.1994C>T p.A665V (on ENST00000651564; = p.A618V on NM_015692.5) | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV52234755; called by muse, mutect2, varscan2
- CPSF6 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); catalogued as rs753465837; called by muse, mutect2, varscan2
- CREM | c.364A>G p.R122G (on ENST00000429130; = p.R73G on NM_001881.3) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs188189426; called by muse, mutect2, varscan2
- CRISPLD2 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 100/283 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.143); catalogued as rs372363505; called by muse, mutect2, varscan2
- CSMD1 | c.9422G>A p.R3141H (on ENST00000520002; = p.R3140H on NM_033225.6) | Missense Mutation (SNP) | VAF 105/241 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs768149539, COSV59277588; called by muse, mutect2, varscan2
- CYP2D7 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 66/363 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs764888846; called by muse, mutect2, varscan2
- D2HGDH | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1472114573, COSV58319342; called by muse, mutect2, varscan2
- DBH | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 171/450 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs199566547; called by muse, mutect2, varscan2
- DCAF13 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs868133848; called by muse, mutect2, varscan2
- DCHS1 | c.4222C>T p.R1408C | Missense Mutation (SNP) | VAF 141/332 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs772193454; called by muse, mutect2, varscan2
- DIAPH3 | c.3497del p.K1166Rfs*49 | Frame Shift Del (DEL) | VAF 36/228 reads (16%) | catalogued as rs749399334, COSV100931069; called by mutect2, pindel, varscan2
- DKK4 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 34/245 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as rs764520274, COSV55183577; called by muse, mutect2, varscan2
- DLEC1 | c.3314C>T p.A1105V | Missense Mutation (SNP) | VAF 148/402 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs780446743, COSV57300501; called by muse, mutect2, varscan2
- DMBT1 | c.7462C>T p.R2488C (on ENST00000338354 / NM_001377530.1; = p.R1731C on NM_004406.3) | Missense Mutation (SNP) | VAF 166/622 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs1437407547; called by muse, mutect2, varscan2
- DNAH5 | c.4389G>A p.W1463* | Nonsense Mutation (SNP) | VAF 25/424 reads (6%) | catalogued as rs758550738, COSV54255499; called by muse, mutect2
- DOCK5 | c.966del p.F322Lfs*5 | Frame Shift Del (DEL) | VAF 59/155 reads (38%) | catalogued as rs36119599; called by mutect2, pindel, varscan2
- DRC3 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.106); catalogued as rs757392054; called by muse, mutect2, varscan2
- DSCAM | c.4862G>A p.R1621Q | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.788); catalogued as rs367647810, COSV101259937; called by muse, mutect2, varscan2
- EIF5B | c.608del p.N203Ifs*10 | Frame Shift Del (DEL) | VAF 25/76 reads (33%) | catalogued as rs1176235101, COSV56813285; called by mutect2, varscan2
- EML3 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1465554218; called by muse, mutect2, varscan2
- EP400 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 63/171 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs200859619; called by muse, mutect2, varscan2
- EP400 | c.8863G>A p.V2955I | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.922); catalogued as rs747186520, COSV57779724; called by muse, mutect2
- FAM131B | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 148/458 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs759366087, COSV58367322, COSV58375458; called by muse, mutect2, varscan2
- FAM186A | c.5432C>T p.A1811V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs765273273; called by muse, mutect2, varscan2
- FEV | c.704dup p.H236Pfs*18 | Frame Shift Ins (INS) | VAF 15/49 reads (31%) | catalogued as rs141171754; called by mutect2, pindel, varscan2
- FKBP8 | c.779C>T p.T260M (on ENST00000222308 / NM_001308373.2; = p.T261M on NM_012181.5) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV55893476; called by muse, mutect2, varscan2
- FLNC | c.4480C>T p.R1494W | Missense Mutation (SNP) | VAF 259/750 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs779079128, COSV100367757; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXC2 | c.275_277del p.K92del | In Frame Del (DEL) | VAF 276/904 reads (31%) | catalogued as rs1203250715; called by pindel, varscan2
- FOXD3 | c.1178G>A p.G393D | Missense Mutation (SNP) | VAF 78/199 reads (39%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.074); catalogued as rs943720041; called by muse, mutect2, varscan2
- FOXE1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 47/254 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV64300120; called by muse, mutect2, varscan2
- FRMPD4 | c.3313del p.S1105Vfs*3 | Frame Shift Del (DEL) | VAF 87/297 reads (29%) | catalogued as rs35659462; called by mutect2, pindel, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 30/116 reads (26%) | catalogued as rs749150409; called by mutect2, varscan2
- GOLGA1 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1394891575; called by muse, mutect2, varscan2
- GPAT2 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 52/207 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752511500; called by muse, mutect2, varscan2
- GPR137B | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 80/452 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs147078955; called by muse, mutect2, varscan2
- GPR50 | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs760818840; called by muse, mutect2
- HNRNPA1 | c.18T>G p.S6= | Splice Region (SNP) | VAF 49/102 reads (48%) | catalogued as rs755898648; called by muse, mutect2, varscan2
- HSPA12A | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 70/293 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs781809567; called by muse, mutect2, varscan2
- INPP4A | c.2930C>T p.T977M (on ENST00000074304 / NM_001134224.1; = p.T938M on NM_004027.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1559132688, COSV50789938; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 27/92 reads (29%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- ITGB6 | c.2330G>A p.R777K | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51791808, COSV51798615; called by muse, mutect2, varscan2
- JAK1 | c.1289dup p.L431Vfs*22 | Frame Shift Ins (INS) | VAF 30/81 reads (37%) | catalogued as rs755650243; called by mutect2, varscan2
- KCNH3 | c.2123del p.G708Efs*11 | Frame Shift Del (DEL) | VAF 74/198 reads (37%) | catalogued as rs1229306184; called by mutect2, pindel, varscan2
- KDM5A | c.2345G>A p.R782Q | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as COSV66990391; called by muse, mutect2, varscan2
- KDM6A | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65040820; called by muse, mutect2, varscan2
- KHDC1 | c.581G>A p.S194N (on ENST00000370384 / NM_001251874.2; = p.S121N on NM_030568.5) | Missense Mutation (SNP) | VAF 124/343 reads (36%) | SIFT tolerated, low confidence (0.5); PolyPhen probably damaging (0.916); catalogued as rs962762004, COSV57615383; called by muse, mutect2, varscan2
- KMT2B | c.7030G>A p.A2344T | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs755245377; called by muse, mutect2, varscan2
- KMT2D | c.10744C>T p.R3582W | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56491153; called by muse, varscan2
- KMT2D | c.5927C>T p.S1976L | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV56468464; called by muse, mutect2, varscan2
- LAGE3 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.117); catalogued as COSV62074504; called by muse, mutect2, varscan2
- LANCL2 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 135/386 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.487); catalogued as rs770121457, COSV54649883; called by muse, mutect2, varscan2
- LILRB5 | c.1526G>A p.G509D (on ENST00000449561 / NM_001081442.3; = p.G508D on NM_006840.5) | Missense Mutation (SNP) | VAF 55/190 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as COSV60260780; called by muse, mutect2, varscan2
- LTB | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs567302751, COSV53000420; called by muse, mutect2, varscan2
- MAGI2 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV62640251; called by muse, mutect2, varscan2
- MAGIX | c.958dup p.A320Gfs*88 | Frame Shift Ins (INS) | VAF 43/135 reads (32%) | catalogued as rs1321319432; called by mutect2, pindel, varscan2
- MAML3 | c.2426A>G p.Q809R | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.388); catalogued as rs1171552463; called by muse, varscan2
- MAN2C1 | c.2983C>T p.Q995* | Nonsense Mutation (SNP) | VAF 110/321 reads (34%) | catalogued as COSV99145269; called by muse, mutect2, varscan2
- MRC2 | c.1412C>A p.P471H | Missense Mutation (SNP) | VAF 97/339 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57640762; called by muse, mutect2, varscan2
- MTERF3 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs750850029; called by muse, mutect2, varscan2
- MTFMT | c.869A>G p.E290G | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as rs1179897414; called by muse, mutect2, varscan2
- MYLK | c.4813G>T p.D1605Y | Missense Mutation (SNP) | VAF 169/474 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60610051; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 44/172 reads (26%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NFX1 | c.1441C>T p.R481* | Nonsense Mutation (SNP) | VAF 28/113 reads (25%) | catalogued as rs1451971621; called by muse, mutect2, varscan2
- NISCH | c.2738C>T p.T913M | Missense Mutation (SNP) | VAF 34/282 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1017181336, COSV61898614; called by muse, mutect2, varscan2
- NOTCH1 | c.3179T>C p.V1060A | Missense Mutation (SNP) | VAF 180/490 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53082811; called by muse, mutect2, varscan2
- NRROS | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 61/176 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751058757, COSV60744792; called by muse, mutect2, varscan2
- ODF3L2 | c.49dup p.L17Pfs*62 | Frame Shift Ins (INS) | VAF 29/74 reads (39%) | catalogued as rs748636054; called by mutect2, pindel, varscan2
- OGA | c.1578del p.M527Cfs*27 | Frame Shift Del (DEL) | VAF 70/324 reads (22%) | catalogued as COSV63382218; called by mutect2, pindel, varscan2
- OGFOD3 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 119/305 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs756501679, COSV57339492; called by muse, mutect2, varscan2
- OR12D2 | c.160C>T p.H54Y | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as rs752585138, COSV65828725; called by muse, mutect2, varscan2
- OR13G1 | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 41/231 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1558292655; called by muse, mutect2, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 58/528 reads (11%) | catalogued as rs761899382; called by mutect2, varscan2
- OR2A12 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 140/394 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.26); catalogued as rs749726901, COSV68822033; called by muse, mutect2, varscan2
- OR52D1 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 89/273 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760829167, COSV59487388; called by muse, mutect2, varscan2
- OR5B2 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.393); catalogued as rs199556711; called by muse, mutect2, varscan2
- OR6C4 | c.616A>G p.M206V | Missense Mutation (SNP) | VAF 74/213 reads (35%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs750194566; called by muse, mutect2, varscan2
- OTUD7B | c.1976del p.G659Vfs*169 | Frame Shift Del (DEL) | VAF 44/265 reads (17%) | catalogued as COSV100967422; called by mutect2, pindel
- PARD3B | c.2171C>T p.A724V | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.102); catalogued as COSV62502529; called by muse, mutect2, varscan2
- PAX5 | c.76dup p.V26Gfs*49 | Frame Shift Ins (INS) | VAF 56/182 reads (31%) | catalogued as rs767894241; called by mutect2, varscan2
- PAXIP1 | c.300del p.F100Lfs*31 | Frame Shift Del (DEL) | VAF 22/45 reads (49%) | catalogued as rs753190856; called by mutect2, varscan2
- PBRM1 | c.1730A>G p.N577S | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs115997236; called by muse, mutect2, varscan2
- PCDHA5 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 131/348 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.232); catalogued as COSV65352687, COSV65353320, COSV65354029; called by muse, varscan2
- PCDHGB4 | c.1927G>A p.A643T | Missense Mutation (SNP) | VAF 18/521 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.166); catalogued as COSV53951428; called by muse, mutect2
- PCLO | c.8192G>A p.R2731H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200140697, COSV61622195; called by muse, mutect2, varscan2
- PCLO | c.7265del p.P2422Lfs*22 | Frame Shift Del (DEL) | VAF 39/122 reads (32%) | catalogued as rs1262793592; called by pindel, varscan2
- PDE2A | c.2266C>T p.R756C | Missense Mutation (SNP) | VAF 71/186 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs138870390, COSV57811844; called by muse, mutect2, varscan2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 26/80 reads (33%) | catalogued as rs759495724; called by mutect2, varscan2
- PEAK1 | c.2839C>T p.R947* | Nonsense Mutation (SNP) | VAF 30/294 reads (10%) | catalogued as rs538475609, COSV56935136; called by muse, mutect2, varscan2
- PGAP6 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 102/370 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs758802749; called by muse, mutect2
- PHACTR4 | c.2032G>T p.E678* (on ENST00000373839 / NM_001350159.2; = p.E688* on NM_023923.4) | Nonsense Mutation (SNP) | VAF 35/95 reads (37%) | catalogued as COSV65783415, COSV65785417; called by muse, mutect2, varscan2
- PI4KA | c.5219A>G p.K1740R | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as rs1390556648, COSV55402756; called by muse, mutect2
- PI4KA | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs1460046498, COSV55412316, COSV55422086; called by muse, mutect2, varscan2
- PIAS4 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs765883460; called by muse, mutect2, varscan2
- PIK3C2B | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as rs373236355; called by muse, mutect2, varscan2
- PKP3 | c.2260_2262del p.K754del | In Frame Del (DEL) | VAF 42/132 reads (32%) | catalogued as rs755089774; called by pindel, varscan2
- PLEKHM1 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 80/259 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1251964349, COSV69598825; called by mutect2, varscan2
- PLXNB2 | c.3733G>A p.V1245M | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63780015; called by muse, mutect2
- PMFBP1 | c.929A>G p.H310R | Missense Mutation (SNP) | VAF 73/199 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.528); catalogued as rs1480138422; called by muse, mutect2, varscan2
- POLD1 | c.2789C>T p.A930V | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs1060501855; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR3GL | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs370170498; called by muse, mutect2
- PPP4R2 | c.52A>G p.K18E | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs1230961376; called by muse, mutect2, varscan2
- PRDM13 | c.1869C>A p.H623Q | Missense Mutation (SNP) | VAF 249/637 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375460946; called by muse, mutect2, varscan2
- PTH1R | c.1234G>A p.V412M | Missense Mutation (SNP) | VAF 219/576 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752454624, COSV57315208; called by muse, mutect2, varscan2
- PWWP2B | c.257del p.P86Lfs*100 | Frame Shift Del (DEL) | VAF 36/144 reads (25%) | catalogued as rs1234606471; called by mutect2, varscan2
- RARRES1 | c.551T>C p.I184T | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs756213840; called by muse, mutect2, varscan2
- RASSF4 | c.41G>A p.S14N | Missense Mutation (SNP) | VAF 54/234 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.065); catalogued as rs748139811; called by muse, mutect2, varscan2
- RBM47 | c.799G>A p.G267S | Missense Mutation (SNP) | VAF 61/491 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55938763; called by muse, varscan2
- RDH11 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.269); catalogued as rs563954790, COSV101191426; called by muse, mutect2, varscan2
- RGS12 | c.3870del p.Q1292Rfs*49 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as rs751982308; called by mutect2, varscan2
- RNF39 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.94); PolyPhen benign (0.134); catalogued as rs773266930; called by muse, mutect2, varscan2
- RPL7L1 | c.460C>A p.L154M | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100491742; called by muse, mutect2, varscan2
- RXFP1 | c.1823A>G p.Q608R | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs776423555; called by muse, mutect2, varscan2
- SALL2 | c.1586del p.P529Qfs*22 | Frame Shift Del (DEL) | VAF 25/73 reads (34%) | catalogued as rs755171367; called by mutect2, pindel, varscan2
- SASS6 | c.170del p.L57Yfs*14 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | catalogued as rs763290832; called by mutect2, varscan2
- SCNN1D | c.53del p.G18Afs*179 (on ENST00000338555; = p.A151Lfs*18 on NM_001130413.4) | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | catalogued as rs1270083658; called by mutect2, pindel
- SEMA6C | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 30/468 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1214468588, COSV59002376; called by muse, mutect2
- SIGLEC12 | c.622C>A p.P208T (on ENST00000291707 / NM_053003.4; = p.P90T on NM_033329.2) | Missense Mutation (SNP) | VAF 107/253 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV52463588; called by muse, mutect2, varscan2
- SIPA1 | c.748_750del p.K250del | In Frame Del (DEL) | VAF 38/103 reads (37%) | catalogued as rs1333397145; called by mutect2, pindel, varscan2
- SKIV2L | c.1637del p.G546Afs*83 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as COSV64814087; called by mutect2, varscan2
- SLC2A11 | c.895G>A p.V299M (on ENST00000345044 / NM_001024938.4; = p.V306M on NM_030807.5) | Missense Mutation (SNP) | VAF 105/311 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs773866178; called by muse, mutect2, varscan2
- SLC43A2 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 80/230 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.577); catalogued as rs746970383; called by muse, mutect2, varscan2
- SLC4A2 | c.1120C>A p.L374M | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV59657956; called by muse, mutect2, varscan2
- SMC3 | c.127del p.Y43Mfs*69 | Frame Shift Del (DEL) | VAF 34/139 reads (24%) | catalogued as rs1466680694; called by mutect2, pindel, varscan2
- SMG6 | c.866G>T p.R289M | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV99558920; called by muse, mutect2
- SPATC1L | c.580C>T p.R194C (on ENST00000291672 / NM_001142854.2; = p.R40C on NM_032261.5) | Missense Mutation (SNP) | VAF 94/272 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs751537273; called by muse, mutect2, varscan2
- SPEF2 | c.877dup p.I293Nfs*6 | Frame Shift Ins (INS) | VAF 38/106 reads (36%) | catalogued as rs1390109415; called by mutect2, varscan2
- SPEN | c.565C>T p.R189* | Nonsense Mutation (SNP) | VAF 190/456 reads (42%) | catalogued as rs1307834195, COSV65365281; called by muse, mutect2, varscan2
- SPEN | c.1732G>A p.G578S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.546); catalogued as rs763959899, COSV65359777; called by muse, mutect2, varscan2
- SPSB4 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 40/214 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs776085694, COSV60150454; called by muse, mutect2, varscan2
- SPTA1 | c.3140G>A p.R1047Q | Missense Mutation (SNP) | VAF 126/626 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs752468147; called by muse, mutect2, varscan2
- SPTBN5 | c.5171G>A p.R1724Q | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs199701887; called by muse, mutect2, varscan2
- SRRM1 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 92/264 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.53); catalogued as rs1266741422; called by muse, mutect2, varscan2
- SRRM4 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 85/218 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs377333031; called by muse, mutect2, varscan2
- TBX4 | c.1112del p.P371Lfs*8 | Frame Shift Del (DEL) | VAF 46/119 reads (39%) | catalogued as rs754897911; ClinVar: uncertain significance; called by mutect2, varscan2
- TCF25 | c.393del p.K131Nfs*17 | Frame Shift Del (DEL) | VAF 32/104 reads (31%) | catalogued as rs748021112; called by mutect2, varscan2
- TDRD1 | c.2825T>C p.I942T | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs1167808824; called by muse, mutect2, varscan2
- TDRKH | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767475622, COSV58617972; called by muse, mutect2, varscan2
- TELO2 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 35/238 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs776490787; called by muse, mutect2, varscan2
- TELO2 | c.933G>A p.T311= | Splice Region (SNP) | VAF 30/170 reads (18%) | catalogued as rs1167542668; called by muse, mutect2, varscan2
- TENT5B | c.1235C>A p.P412H | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56693344; called by muse, mutect2, varscan2
- TET2 | c.2511T>A p.N837K | Missense Mutation (SNP) | VAF 76/213 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs755404521; called by muse, mutect2, varscan2
- TFCP2L1 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 83/262 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55292626; called by muse, mutect2, varscan2
- TMEM184B | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 103/306 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62672464; called by muse, mutect2, varscan2
- TMPO | c.295del p.T99Lfs*12 | Frame Shift Del (DEL) | VAF 37/102 reads (36%) | catalogued as rs770800449; called by mutect2, varscan2
- TRAPPC12 | c.2159C>T p.A720V | Missense Mutation (SNP) | VAF 60/330 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV60845878; called by muse, mutect2, varscan2
- TRAV3 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 74/225 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs745851436; called by muse, mutect2, varscan2
- TRIM2 | c.1087G>A p.A363T (on ENST00000437508; = p.A390T on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as rs754123914; called by muse, mutect2, varscan2
- TRIM31 | c.260A>G p.Q87R | Missense Mutation (SNP) | VAF 85/212 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs928628355; called by muse, mutect2, varscan2
- TRIM9 | c.475C>A p.Q159K | Missense Mutation (SNP) | VAF 132/378 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV100030317; called by muse, mutect2, varscan2
- TRIOBP | c.2758C>T p.R920* | Nonsense Mutation (SNP) | VAF 30/179 reads (17%) | catalogued as rs1328461856, CM154690; called by muse, mutect2, varscan2
- TRPV1 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs903705338, COSV51518182; called by muse, mutect2, varscan2
- TUBA3D | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 81/246 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.203); catalogued as rs745718611, COSV58312359; called by muse, mutect2, varscan2
- UBTF | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs1168315138, COSV57186395; called by muse, mutect2
- USP33 | c.2753G>A p.R918Q | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.401); catalogued as rs749382743, COSV62468280; called by muse, mutect2, varscan2
- VANGL2 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 92/362 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.144); catalogued as COSV100925573; called by muse, mutect2, varscan2
- WDFY4 | c.7295G>A p.C2432Y | Missense Mutation (SNP) | VAF 42/375 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs1214976776; called by muse, mutect2, varscan2
- XIRP1 | c.1228G>A p.G410S | Missense Mutation (SNP) | VAF 63/185 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs775595813, COSV100453679; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 111/410 reads (27%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- ZBED2 | c.27G>T p.E9D | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.023); catalogued as COSV51920425; called by muse, mutect2, varscan2
- ZBED8 | c.894_897del p.N299Sfs*21 | Frame Shift Del (DEL) | VAF 30/93 reads (32%) | catalogued as rs1184980267; called by mutect2, pindel, varscan2
- ZDHHC8 | c.1374del p.T459Rfs*177 | Frame Shift Del (DEL) | VAF 38/126 reads (30%) | catalogued as rs781677398, COSV57709922; called by mutect2, pindel, varscan2
- ZFHX2 | c.4709G>A p.R1570Q | Missense Mutation (SNP) | VAF 32/455 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.289); catalogued as rs1004295168; called by muse, mutect2
- ZKSCAN2 | c.1183A>G p.T395A | Missense Mutation (SNP) | VAF 48/268 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV60156375; called by muse, mutect2, varscan2
- ZNF496 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.184); catalogued as rs758982919, COSV54175637; called by muse, mutect2, varscan2
- ZNF512B | c.2290G>A p.V764M | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs768660385, COSV53871876; called by muse, mutect2, varscan2
- ZNF554 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV100421369; called by muse, mutect2
- ZNF675 | c.110A>G p.Y37C | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747899431; called by muse, mutect2, varscan2
- ZNF697 | c.1547del p.T516Rfs*66 | Frame Shift Del (DEL) | VAF 78/274 reads (28%) | catalogued as COSV70284359; called by mutect2, pindel, varscan2
- ABCB8 | c.1193G>A p.G398D (on ENST00000297504 / NM_001282291.2; = p.G381D on NM_007188.5) | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- AC069544.2 | c.131A>G p.Q44R | Missense Mutation (SNP) | VAF 19/545 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- ACAP3 | c.1196G>A p.G399D | Missense Mutation (SNP) | VAF 244/607 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACBD3 | c.328T>A p.L110M | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTN4 | c.2332G>A p.D778N | Missense Mutation (SNP) | VAF 185/519 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM21 | c.902del p.N301Ifs*4 | Frame Shift Del (DEL) | VAF 49/132 reads (37%) | called by mutect2, varscan2
- ADAM30 | c.2102T>C p.L701P | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ADAM8 | c.308A>G p.D103G | Missense Mutation (SNP) | VAF 15/351 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.315); called by muse, mutect2
- ADCY3 | c.2186A>G p.Q729R | Missense Mutation (SNP) | VAF 90/200 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.046); called by muse, varscan2
- AHRR | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- AKAP9 | c.6111dup p.L2038Tfs*8 (on ENST00000359028; = p.L2006Tfs*8 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 24/57 reads (42%) | called by mutect2, pindel, varscan2
- AOC3 | c.957A>C p.Q319H | Missense Mutation (SNP) | VAF 121/338 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- APBA2 | c.1918-1G>T p.X640_splice | Splice Site (SNP) | VAF 81/491 reads (16%) | called by muse, mutect2, varscan2
- APBB2 | c.1553A>T p.K518I (on ENST00000295974 / NM_001166050.2; = p.K519I on NM_004307.2) | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- ARAP3 | c.1180del p.R394Dfs*21 | Frame Shift Del (DEL) | VAF 88/270 reads (33%) | called by mutect2, pindel, varscan2
- ARID1A | c.4899del p.M1634* | Frame Shift Del (DEL) | VAF 31/105 reads (30%) | called by mutect2, pindel, varscan2
- ARID5A | c.1772dup p.N591Kfs*33 | Frame Shift Ins (INS) | VAF 73/226 reads (32%) | called by mutect2, pindel, varscan2
- ATP13A3 | c.148A>G p.M50V | Missense Mutation (SNP) | VAF 75/238 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ATP2B1 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ATP2B4 | c.49A>C p.S17R | Missense Mutation (SNP) | VAF 54/270 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- BCL11A | c.691del p.L231Cfs*15 (on ENST00000335712 / NM_001365609.1; = p.L265Cfs*15 on NM_018014.4) | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- BIVM-ERCC5 | c.4067del p.N1356Ifs*4 | Frame Shift Del (DEL) | VAF 27/235 reads (11%) | called by mutect2, pindel, varscan2
- BSCL2 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 170/476 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- C16orf89 | c.1120A>G p.T374A | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CACNA2D1 | c.2711G>A p.C904Y (on ENST00000356253 / NM_001366867.1; = p.C892Y on NM_000722.4) | Missense Mutation (SNP) | VAF 26/281 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- CACUL1 | c.165del p.Q56Sfs*32 | Frame Shift Del (DEL) | VAF 40/394 reads (10%) | called by mutect2, pindel, varscan2
- CATSPERE | c.1551A>G p.I517M | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CBX2 | c.977dup p.H329Afs*84 | Frame Shift Ins (INS) | VAF 42/140 reads (30%) | called by mutect2, pindel, varscan2
- CCDC85C | c.1028G>A p.S343N | Missense Mutation (SNP) | VAF 97/294 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- CD6 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 87/278 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CDH17 | c.1504del p.V502Lfs*13 | Frame Shift Del (DEL) | VAF 43/127 reads (34%) | called by mutect2, pindel, varscan2
- CEACAM19 | c.460A>G p.T154A | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP78 | c.904A>G p.M302V | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CHPT1 | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CHST7 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 114/291 reads (39%) | called by muse, mutect2, varscan2
- CILP2 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- CMIP | c.805C>T p.R269* (on ENST00000537098 / NM_198390.2; = p.R175* on NM_030629.3) | Nonsense Mutation (SNP) | VAF 69/170 reads (41%) | called by muse, mutect2, varscan2
- CNOT1 | c.6575T>G p.F2192C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- COCH | c.1267T>C p.C423R (on ENST00000216361 / NM_001347720.1; = p.C358R on NM_004086.3) | Missense Mutation (SNP) | VAF 86/246 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COX10 | c.1115_1116insA p.V373Cfs*92 | Frame Shift Ins (INS) | VAF 101/288 reads (35%) | called by mutect2, pindel, varscan2
- CRAMP1 | c.1938dup p.A647Rfs*29 | Frame Shift Ins (INS) | VAF 33/129 reads (26%) | called by mutect2, pindel, varscan2
- CRHR2 | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 89/216 reads (41%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- CRY2 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CSMD2 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- CSMD3 | c.9577C>T p.Q3193* (on ENST00000297405 / NM_001363185.1; = p.Q3024* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 83/202 reads (41%) | called by muse, mutect2, varscan2
- CYTH2 | c.1134C>A p.D378E (on ENST00000427476; = p.D377E on NM_004228.7) | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- DCAF1 | c.2677G>A p.A893T | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2
- DCHS1 | c.2618del p.P873Qfs*5 | Frame Shift Del (DEL) | VAF 128/406 reads (32%) | called by mutect2, pindel, varscan2
- DDR2 | c.2189G>A p.G730E | Missense Mutation (SNP) | VAF 93/531 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DMTF1 | c.1352C>T p.T451I | Missense Mutation (SNP) | VAF 84/266 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DNAH1 | c.11242C>T p.H3748Y | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- DNAJB11 | c.574G>T p.V192F | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- DNHD1 | c.5237C>T p.P1746L | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DOCK2 | c.144C>A p.Y48* | Nonsense Mutation (SNP) | VAF 39/137 reads (28%) | called by muse, mutect2, varscan2
- E2F8 | c.1433del p.P478Qfs*2 | Frame Shift Del (DEL) | VAF 69/223 reads (31%) | called by mutect2, pindel, varscan2
- ECHDC1 | c.136del p.T46Hfs*24 (on ENST00000531967 / NM_001139510.1; = p.T40Hfs*24 on NM_018479.3) | Frame Shift Del (DEL) | VAF 53/137 reads (39%) | called by mutect2, pindel, varscan2
- EEPD1 | c.32T>C p.I11T | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- EHF | c.712A>G p.R238G | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ELAPOR2 | c.833del p.N278Ifs*47 (on ENST00000450689 / NM_001142749.3; = p.N111Ifs*47 on NM_152748.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 26/82 reads (32%) | called by mutect2, pindel, varscan2
- EP400 | c.3949C>T p.H1317Y | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ERICH3 | c.2296del p.T766Rfs*23 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | called by mutect2, pindel, varscan2
- ESYT1 | c.28A>G p.S10G | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- ETFRF1 | c.128del p.N43Tfs*4 | Frame Shift Del (DEL) | VAF 23/80 reads (29%) | called by mutect2, pindel, varscan2
- FBN2 | c.7240G>T p.G2414C | Missense Mutation (SNP) | VAF 203/535 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- FBXW7 | c.664_667delinsAG p.R223Pfs*32 (on ENST00000281708 / NM_001349798.2; = p.R143Pfs*32 on NM_018315.5) | Frame Shift Del (DEL) | VAF 51/214 reads (24%) | called by pindel, varscan2*
- FCSK | c.2912C>T p.A971V | Missense Mutation (SNP) | VAF 112/363 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- FMNL1 | c.240dup p.A81Rfs*23 | Frame Shift Ins (INS) | VAF 59/277 reads (21%) | called by mutect2, pindel, varscan2
- FOXO3 | c.212del p.G71Dfs*49 | Frame Shift Del (DEL) | VAF 55/196 reads (28%) | called by mutect2, pindel, varscan2
- FSIP2 | c.20722T>C p.*6908Rext*5 | Nonstop Mutation (SNP) | VAF 12/39 reads (31%) | called by muse, varscan2
- FTO | c.690G>A p.W230* | Nonsense Mutation (SNP) | VAF 108/264 reads (41%) | called by muse, mutect2, varscan2
- FZD4 | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GABRA6 | c.211T>C p.S71P | Missense Mutation (SNP) | VAF 110/329 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALNT7 | c.1004G>A p.G335D | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GAS2L1 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 13/193 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- GLI3 | c.1978T>C p.S660P | Missense Mutation (SNP) | VAF 148/402 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GMNN | c.592A>G p.T198A | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- GON4L | c.1189A>G p.T397A | Missense Mutation (SNP) | VAF 102/566 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GPAM | c.1961G>A p.G654D | Missense Mutation (SNP) | VAF 58/254 reads (23%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR75 | c.719del p.P240Lfs*2 | Frame Shift Del (DEL) | VAF 76/232 reads (33%) | called by mutect2, pindel, varscan2
- GRIN2B | c.99del p.S34Afs*38 | Frame Shift Del (DEL) | VAF 65/221 reads (29%) | called by mutect2, pindel, varscan2
- GSTA3 | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- H2BC12 | c.174G>T p.K58N | Missense Mutation (SNP) | VAF 60/395 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- HDHD2 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- HEATR3 | c.1090C>T p.Q364* | Nonsense Mutation (SNP) | VAF 15/186 reads (8%) | called by muse, mutect2
- HERC1 | c.14137C>T p.P4713S | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HGS | c.1067A>G p.E356G | Missense Mutation (SNP) | VAF 83/247 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- HIVEP1 | c.6791A>G p.Q2264R | Missense Mutation (SNP) | VAF 72/182 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- HIVEP2 | c.1091_1092del p.T364Sfs*18 | Frame Shift Del (DEL) | VAF 44/164 reads (27%) | called by pindel, varscan2
- HOXA5 | c.282C>A p.H94Q | Missense Mutation (SNP) | VAF 93/248 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- HSPB1 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 151/463 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- ICAM5 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 80/203 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- IGF1R | c.587C>T p.T196I | Missense Mutation (SNP) | VAF 84/236 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- IL3RA | c.898_901del p.N300Hfs*9 | Frame Shift Del (DEL) | VAF 108/271 reads (40%) | called by mutect2, pindel, varscan2
- IL6ST | c.5T>C p.L2S | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INKA2 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 14/344 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2
- INPPL1 | c.2337_2339del p.K779_S780delinsN | In Frame Del (DEL) | VAF 23/91 reads (25%) | called by mutect2, pindel, varscan2
- IRS2 | c.3965G>A p.S1322N | Missense Mutation (SNP) | VAF 110/295 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- IRX2 | c.305dup p.Y103Vfs*87 | Frame Shift Ins (INS) | VAF 27/177 reads (15%) | called by mutect2, pindel, varscan2
- ITGA1 | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- ITGA6 | c.276del p.P93Hfs*37 | Frame Shift Del (DEL) | VAF 165/438 reads (38%) | called by mutect2, varscan2
- JAK1 | c.2405_2408del p.K802Rfs*11 | Frame Shift Del (DEL) | VAF 45/152 reads (30%) | called by mutect2, pindel, varscan2
- JAM3 | c.240del p.F80Lfs*21 | Frame Shift Del (DEL) | VAF 97/300 reads (32%) | called by mutect2, pindel, varscan2
- JARID2 | c.1272del p.R425Gfs*36 | Frame Shift Del (DEL) | VAF 26/87 reads (30%) | called by mutect2, pindel, varscan2
- JPH2 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 130/336 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- KEL | c.1969C>A p.H657N | Missense Mutation (SNP) | VAF 84/451 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIF5B | c.1985A>G p.E662G | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KISS1 | c.169A>C p.K57Q | Missense Mutation (SNP) | VAF 166/929 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- KLF3 | c.677dup p.Q227Afs*37 | Frame Shift Ins (INS) | VAF 20/61 reads (33%) | called by mutect2, varscan2
- KLHL13 | c.755G>A p.C252Y | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- KLHL26 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- KLHL29 | c.1008A>C p.E336D | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- KMT2B | c.4498-1G>C p.X1500_splice | Splice Site (SNP) | VAF 37/117 reads (32%) | called by muse, mutect2, varscan2
- LAMA1 | c.9121A>G p.R3041G | Missense Mutation (SNP) | VAF 126/320 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LAMA3 | c.5044G>T p.G1682* (on ENST00000313654 / NM_198129.4; = p.G73* on NM_000227.6) | Nonsense Mutation (SNP) | VAF 22/210 reads (10%) | called by muse, mutect2, varscan2
- LARP1 | c.911del p.P304Qfs*22 (on ENST00000518297 / NM_033551.3; = p.P227Qfs*22 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 76/274 reads (28%) | called by pindel, varscan2
- LDLR | c.2530G>T p.G844C | Missense Mutation (SNP) | VAF 115/333 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LMX1A | c.104G>A p.C35Y | Missense Mutation (SNP) | VAF 83/342 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRCH3 | c.997dup p.S333Ffs*12 | Frame Shift Ins (INS) | VAF 22/76 reads (29%) | called by mutect2, pindel, varscan2
- LYST | c.8494A>G p.S2832G | Missense Mutation (SNP) | VAF 49/228 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAN2B1 | c.2178del p.K727Rfs*39 | Frame Shift Del (DEL) | VAF 167/482 reads (35%) | called by mutect2, pindel, varscan2
- MAP1B | c.3196A>G p.T1066A | Missense Mutation (SNP) | VAF 98/314 reads (31%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- MARK3 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- MDC1 | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 106/281 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- MEN1 | c.881T>A p.L294Q | Missense Mutation (SNP) | VAF 193/512 reads (38%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MFN2 | c.2070-7T>C | Splice Region (SNP) | VAF 73/541 reads (13%) | called by muse, mutect2, varscan2
- MGRN1 | c.1283G>A p.C428Y | Missense Mutation (SNP) | VAF 121/356 reads (34%) | SIFT tolerated, low confidence (0.46); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- MIPEP | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MKNK2 | c.869G>A p.S290N | Missense Mutation (SNP) | VAF 71/206 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- MPHOSPH8 | c.641A>G p.K214R | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- NAV3 | c.7153C>A p.L2385I (on ENST00000397909 / NM_001024383.2; = p.L2363I on NM_014903.6) | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NCDN | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- NECAB1 | c.84G>T p.M28I | Missense Mutation (SNP) | VAF 93/286 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- NHS | c.1462del p.R488Gfs*68 | Frame Shift Del (DEL) | VAF 64/210 reads (30%) | called by mutect2, pindel, varscan2
- NMD3 | c.-20-9_-20-5del | Splice Region (DEL) | VAF 18/67 reads (27%) | called by mutect2, varscan2*
- NOL6 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 89/327 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NPR3 | c.428T>C p.V143A | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUMA1 | c.25del p.A9Lfs*7 | Frame Shift Del (DEL) | VAF 81/253 reads (32%) | called by mutect2, varscan2
- NUP214 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NUP42 | c.77G>T p.R26M | Missense Mutation (SNP) | VAF 70/207 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- NYAP1 | c.1714del p.V572Cfs*2 | Frame Shift Del (DEL) | VAF 41/141 reads (29%) | called by mutect2, pindel, varscan2
- OR2A5 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 22/335 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- OR2C1 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ORC1 | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- ORC5 | c.1029dup p.H344Tfs*25 | Frame Shift Ins (INS) | VAF 14/40 reads (35%) | called by mutect2, varscan2
- OTOG | c.5639del p.P1880Qfs*99 | Frame Shift Del (DEL) | VAF 153/459 reads (33%) | called by mutect2, pindel, varscan2
- P2RX2 | c.869C>A p.P290H (on ENST00000343948 / NM_170683.4; = p.P218H on NM_012226.5) | Missense Mutation (SNP) | VAF 115/330 reads (35%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- P4HA2 | c.82+2T>A p.X28_splice | Splice Site (SNP) | VAF 53/138 reads (38%) | called by muse, mutect2, varscan2
- PAPOLA | c.958T>G p.Y320D | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PAPSS1 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 152/377 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PBX3 | c.467T>C p.L156S | Missense Mutation (SNP) | VAF 75/185 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA3 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHGA3 | c.2224G>T p.G742C | Missense Mutation (SNP) | VAF 196/558 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCK1 | c.1646G>A p.S549N | Missense Mutation (SNP) | VAF 144/386 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE3A | c.2091del p.F697Lfs*3 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | called by mutect2, pindel, varscan2
- PDPR | c.2341C>A p.L781I | Missense Mutation (SNP) | VAF 115/447 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- PHACTR4 | c.2009C>T p.A670V (on ENST00000373839 / NM_001350159.2; = p.A680V on NM_023923.4) | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.185); called by muse, mutect2
- PIGB | c.1151G>A p.W384* | Nonsense Mutation (SNP) | VAF 46/100 reads (46%) | called by muse, mutect2, varscan2
- PIGQ | c.1802C>A p.P601H | Missense Mutation (SNP) | VAF 72/218 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- PIK3AP1 | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 74/290 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- PITRM1 | c.2922G>T p.M974I | Missense Mutation (SNP) | VAF 100/366 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, varscan2
- PKP2 | c.752G>C p.S251T | Missense Mutation (SNP) | VAF 161/399 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- PNMA8B | c.1421G>A p.G474D | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- POU3F3 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 171/440 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- PPP1R16A | c.1498A>G p.R500G | Missense Mutation (SNP) | VAF 28/225 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP4R3A | c.373A>G p.M125V | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRCC | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 66/385 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRIMPOL | c.658del p.S220Qfs*47 | Frame Shift Del (DEL) | VAF 69/237 reads (29%) | called by mutect2, pindel, varscan2
- PRMT3 | c.1345A>G p.T449A | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- PRR14 | c.836del p.P279Qfs*2 | Frame Shift Del (DEL) | VAF 26/78 reads (33%) | called by mutect2, pindel
- PRR14L | c.5514del p.K1838Nfs*16 | Frame Shift Del (DEL) | VAF 40/265 reads (15%) | called by mutect2, pindel, varscan2
- PTK7 | c.1320dup p.P441Tfs*35 | Frame Shift Ins (INS) | VAF 47/175 reads (27%) | called by mutect2, pindel, varscan2
- PTPN1 | c.1130del p.G377Efs*27 | Frame Shift Del (DEL) | VAF 36/106 reads (34%) | called by mutect2, pindel, varscan2
- PTPN13 | c.1505G>A p.S502N | Missense Mutation (SNP) | VAF 97/298 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PTPN21 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 120/343 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PTPRQ | c.1045G>T p.G349* (on ENST00000616559; = p.G307* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- RALGAPB | c.4142+2T>C p.X1381_splice | Splice Site (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- RASAL2 | c.918A>T p.E306D | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RBPJ | c.663del p.F221Lfs*42 | Frame Shift Del (DEL) | VAF 19/66 reads (29%) | called by mutect2, pindel, varscan2
- RFX1 | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 83/230 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RLIM | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROCK2 | c.412dup p.W138Lfs*12 | Frame Shift Ins (INS) | VAF 10/36 reads (28%) | called by mutect2, varscan2
- RPE | c.620G>T p.R207I (on ENST00000359429 / NM_001318926.1; = p.R157I on NM_006916.2) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RPS6KA6 | c.2076T>G p.D692E | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RUSF1 | c.184dup p.A62Gfs*23 | Frame Shift Ins (INS) | VAF 28/242 reads (12%) | called by mutect2, pindel, varscan2
- SAGE1 | c.833dup p.N278Kfs*25 | Frame Shift Ins (INS) | VAF 19/148 reads (13%) | called by mutect2, pindel, varscan2
- SCO2 | c.686A>G p.Y229C | Missense Mutation (SNP) | VAF 207/613 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SESN3 | c.269T>A p.L90* | Nonsense Mutation (SNP) | VAF 68/225 reads (30%) | called by muse, mutect2, varscan2
- SETD1B | c.22del p.H8Tfs*27 | Frame Shift Del (DEL) | VAF 43/66 reads (65%) | called by mutect2, varscan2
- SFXN3 | c.853del p.L285Cfs*14 | Frame Shift Del (DEL) | VAF 24/90 reads (27%) | called by mutect2, pindel, varscan2
- SGK1 | c.601T>G p.F201V | Missense Mutation (SNP) | VAF 77/237 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHISA6 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 295/791 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- SHLD2 | c.1285del p.T429Hfs*3 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | called by mutect2, varscan2
- SIK3 | c.2311C>T p.P771S (on ENST00000445177 / NM_001366686.2; = p.P729S on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- SLC8A2 | c.107G>T p.S36I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- SLC9A2 | c.1787G>A p.S596N | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLMAP | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMARCAD1 | c.1217A>G p.Q406R | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SMYD5 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2
- SORCS3 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 118/425 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SSC5D | c.2497C>T p.P833S | Missense Mutation (SNP) | VAF 140/352 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- STOX1 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- SVEP1 | c.9540del p.K3180Nfs*8 | Frame Shift Del (DEL) | VAF 42/165 reads (25%) | called by mutect2, pindel, varscan2
- SYNE1 | c.1903del p.M635Cfs*26 (on ENST00000367255 / NM_182961.4; = p.M642Cfs*26 on NM_033071.3) | Frame Shift Del (DEL) | VAF 120/372 reads (32%) | called by mutect2, pindel, varscan2
- SYNE2 | c.5005dup p.M1669Nfs*8 | Frame Shift Ins (INS) | VAF 33/104 reads (32%) | called by mutect2, pindel, varscan2
- SYNE2 | c.19280del p.G6427Afs*84 | Frame Shift Del (DEL) | VAF 38/259 reads (15%) | called by mutect2, pindel, varscan2
- SYNJ2 | c.2669C>T p.A890V | Missense Mutation (SNP) | VAF 250/697 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SZT2 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TBC1D10B | c.1882C>A p.L628M | Missense Mutation (SNP) | VAF 78/221 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TBC1D22B | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- TCF19 | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TENM3 | c.7903C>T p.R2635C | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- TERB1 | c.365_368del p.S122Ffs*18 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | called by mutect2, pindel, varscan2
- TINAG | c.296dup p.S100Vfs*5 | Frame Shift Ins (INS) | VAF 42/120 reads (35%) | called by mutect2, pindel
- TLK1 | c.968A>G p.Q323R | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TMEM119 | c.240del p.T81Pfs*7 | Frame Shift Del (DEL) | VAF 102/297 reads (34%) | called by mutect2, pindel, varscan2
- TMEM200B | c.451del p.V151Cfs*31 | Frame Shift Del (DEL) | VAF 38/302 reads (13%) | called by mutect2, pindel, varscan2
- TMEM62 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- TRAV3 | c.277T>G p.F93V | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- TRIM41 | c.1806C>A p.H602Q | Missense Mutation (SNP) | VAF 132/347 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- TRIM64C | c.68T>C p.I23T | Missense Mutation (SNP) | VAF 116/308 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TRIM72 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TRMT2A | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 43/260 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC37 | c.3758del p.N1253Ifs*4 | Frame Shift Del (DEL) | VAF 43/167 reads (26%) | called by mutect2, pindel, varscan2
- TTN | c.99470del p.K33157Sfs*12 (on ENST00000591111; = p.K25733Sfs*12 on NM_003319.4) | Frame Shift Del (DEL) | VAF 56/194 reads (29%) | called by pindel, varscan2
- TTN | c.78124A>G p.K26042E (on ENST00000591111; = p.K18618E on NM_003319.4) | Missense Mutation (SNP) | VAF 67/176 reads (38%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UBE3B | c.183del p.F61Lfs*44 | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | called by mutect2, pindel, varscan2
- UQCR10 | c.28T>A p.L10M | Missense Mutation (SNP) | VAF 69/190 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- UQCRC2 | c.1003C>T p.L335F | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- USP16 | c.868G>C p.V290L | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- USP19 | c.1145del p.G382Afs*35 | Frame Shift Del (DEL) | VAF 12/84 reads (14%) | called by mutect2, pindel, varscan2
- USP47 | c.1205G>T p.R402M (on ENST00000399455 / NM_001372095.1; = p.R314M on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WASHC2A | c.1113G>T p.E371D | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZBTB1 | c.1571dup p.Q525Afs*4 | Frame Shift Ins (INS) | VAF 37/101 reads (37%) | called by mutect2, varscan2
- ZFHX3 | c.6996dup p.C2333Mfs*2 | Frame Shift Ins (INS) | VAF 53/178 reads (30%) | called by mutect2, pindel, varscan2
- ZIC5 | c.497del p.P166Lfs*165 | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | called by mutect2, pindel, varscan2
- ZNF292 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ZNF449 | c.830del p.P277Qfs*8 | Frame Shift Del (DEL) | VAF 28/107 reads (26%) | called by mutect2, pindel, varscan2
- ZNFX1 | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- AHNAK | c.14412G>A p.L4804= | Silent (SNP) | VAF 123/328 reads (38%) | called by muse, mutect2, varscan2
- ANHX | c.636G>A p.A212= | Silent (SNP) | VAF 52/138 reads (38%) | catalogued as rs565245948; called by muse, mutect2, varscan2
- ANO1 | c.903G>A p.L301= | Silent (SNP) | VAF 20/196 reads (10%) | catalogued as COSV60287763; called by muse, mutect2, varscan2
- APC2 | c.6129C>T p.C2043= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs1308241401; called by muse, mutect2, varscan2
- ARHGEF17 | c.5055G>A p.E1685= | Silent (SNP) | VAF 54/130 reads (42%) | catalogued as rs1016884567; called by muse, mutect2, varscan2
- ASB4 | c.814C>T p.L272= | Silent (SNP) | VAF 86/229 reads (38%) | called by muse, mutect2, varscan2
- B3GNT9 | c.864C>T p.G288= | Silent (SNP) | VAF 50/134 reads (37%) | catalogued as rs1462443365; called by muse, mutect2, varscan2
- BRWD3 | c.5058C>T p.G1686= | Silent (SNP) | VAF 73/212 reads (34%) | catalogued as rs781010314; called by muse, mutect2, varscan2
- C10orf120 | c.549A>G p.L183= | Silent (SNP) | VAF 44/178 reads (25%) | called by muse, mutect2, varscan2
- C11orf87 | c.435C>T p.N145= | Silent (SNP) | VAF 17/310 reads (5%) | catalogued as COSV59357736; called by muse, mutect2
- C4orf19 | c.448C>T p.L150= | Silent (SNP) | VAF 6/99 reads (6%) | called by muse, mutect2
- C8B | c.660G>A p.T220= | Silent (SNP) | VAF 136/441 reads (31%) | catalogued as rs370360066; called by muse, mutect2, varscan2
- CA14 | c.282G>A p.L94= | Silent (SNP) | VAF 16/386 reads (4%) | called by muse, mutect2
- CAMK2D | c.477C>G p.G159= | Silent (SNP) | VAF 56/180 reads (31%) | called by muse, mutect2, varscan2
- CARMIL2 | c.1683G>A p.R561= | Silent (SNP) | VAF 83/253 reads (33%) | called by muse, mutect2, varscan2
- CBX8 | c.57G>A p.R19= | Silent (SNP) | VAF 79/223 reads (35%) | catalogued as rs1221350080; called by muse, mutect2, varscan2
- CD1E | c.849G>A p.L283= | Silent (SNP) | VAF 27/137 reads (20%) | called by muse, mutect2, varscan2
- CD81 | c.396G>A p.Q132= | Silent (SNP) | VAF 235/629 reads (37%) | called by muse, mutect2, varscan2
- CDCA5 | c.396C>T p.D132= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs765815329, COSV51870761; called by muse, mutect2, varscan2
- CEBPB | c.603G>A p.A201= | Silent (SNP) | VAF 75/179 reads (42%) | catalogued as rs997116351; called by muse, mutect2, varscan2
- CEP350 | c.8976C>T p.N2992= | Silent (SNP) | VAF 7/96 reads (7%) | called by muse, mutect2
- CFAP43 | c.1311C>T p.C437= | Silent (SNP) | VAF 30/193 reads (16%) | catalogued as rs763385783; called by muse, mutect2, varscan2
- COL23A1 | c.402C>T p.D134= | Silent (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- COL4A6 | c.1248C>T p.G416= | Silent (SNP) | VAF 111/286 reads (39%) | called by muse, mutect2, varscan2
- COL9A2 | c.1350C>T p.P450= | Silent (SNP) | VAF 129/389 reads (33%) | catalogued as COSV65622262; called by muse, mutect2, varscan2
- CTH | c.507T>C p.I169= | Silent (SNP) | VAF 17/202 reads (8%) | called by muse, mutect2
- CUEDC1 | c.468C>T p.I156= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs111753270; called by muse, mutect2, varscan2
- CYSLTR1 | c.471A>G p.P157= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs1204079251; called by muse, mutect2, varscan2
- DAXX | c.276G>A p.Q92= | Silent (SNP) | VAF 64/167 reads (38%) | catalogued as COSV56472142; called by muse, mutect2, varscan2
- DDB1 | c.2562G>A p.S854= | Silent (SNP) | VAF 41/108 reads (38%) | catalogued as rs771383564; called by muse, mutect2, varscan2
- DHX16 | c.1398C>A p.A466= | Silent (SNP) | VAF 49/313 reads (16%) | called by muse, mutect2, varscan2
- DLL4 | c.999T>C p.C333= | Silent (SNP) | VAF 75/187 reads (40%) | catalogued as rs773508830; called by muse, mutect2, varscan2
- DLX4 | c.27C>T p.P9= | Silent (SNP) | VAF 23/75 reads (31%) | called by muse, mutect2, varscan2
- DST | c.11112G>A p.V3704= (on ENST00000361203 / NM_001374722.1; = p.V1292= on NM_015548.5) | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs772436994; called by muse, mutect2, varscan2
- DYNC1H1 | c.10518C>T p.D3506= | Silent (SNP) | VAF 168/512 reads (33%) | called by muse, mutect2, varscan2
- EGR2 | c.951G>A p.L317= | Silent (SNP) | VAF 15/342 reads (4%) | called by muse, mutect2
- EPB41L4B | c.1381C>A p.R461= | Silent (SNP) | VAF 29/223 reads (13%) | called by muse, mutect2, varscan2
- FAT2 | c.5760T>C p.P1920= | Silent (SNP) | VAF 27/193 reads (14%) | called by muse, mutect2, varscan2
- FTMT | c.177C>A p.T59= | Silent (SNP) | VAF 55/132 reads (42%) | called by muse, mutect2, varscan2
- GAS2L3 | c.405T>C p.I135= | Silent (SNP) | VAF 59/194 reads (30%) | called by muse, mutect2, varscan2
- GPATCH4 | c.714T>C p.A238= | Silent (SNP) | VAF 76/428 reads (18%) | called by muse, mutect2, varscan2
- H4C1 | c.96G>A p.K32= | Silent (SNP) | VAF 83/203 reads (41%) | called by muse, mutect2, varscan2
- HCAR1 | c.657C>A p.T219= | Silent (SNP) | VAF 100/274 reads (36%) | catalogued as rs767155988; called by muse, mutect2, varscan2
- HCFC2 | c.264G>T p.G88= | Silent (SNP) | VAF 9/121 reads (7%) | catalogued as rs772892790; called by muse, mutect2
- HCRTR1 | c.615C>T p.R205= | Silent (SNP) | VAF 64/158 reads (41%) | called by muse, mutect2
- HECTD4 | c.10530G>A p.L3510= | Silent (SNP) | VAF 72/164 reads (44%) | catalogued as rs1202396543; called by muse, mutect2, varscan2
- HEPACAM | c.381C>T p.T127= | Silent (SNP) | VAF 57/354 reads (16%) | catalogued as rs766390439, COSV53432420; called by muse, mutect2, varscan2
- HIRA | c.1809G>A p.R603= | Silent (SNP) | VAF 53/309 reads (17%) | catalogued as rs762213339; called by muse, mutect2, varscan2
- HOXD9 | c.898C>T p.L300= | Silent (SNP) | VAF 68/192 reads (35%) | called by muse, mutect2, varscan2
- HR | c.1551G>A p.V517= | Silent (SNP) | VAF 14/268 reads (5%) | called by muse, mutect2
- HTR1F | c.153C>T p.T51= | Silent (SNP) | VAF 111/363 reads (31%) | catalogued as COSV60390448; called by muse, mutect2, varscan2
- IBTK | c.2991C>T p.N997= | Silent (SNP) | VAF 26/83 reads (31%) | called by muse, mutect2, varscan2
- IGHE | c.381C>T p.F127= | Silent (SNP) | VAF 149/352 reads (42%) | catalogued as rs868912888; called by muse, mutect2, varscan2
- KBTBD11 | c.1644G>A p.T548= | Silent (SNP) | VAF 77/159 reads (48%) | called by muse, mutect2, varscan2
- KCNMA1 | c.1830C>T p.F610= | Silent (SNP) | VAF 90/315 reads (29%) | catalogued as rs202015764; called by muse, mutect2, varscan2
- KIF7 | c.786G>A p.T262= | Silent (SNP) | VAF 61/404 reads (15%) | catalogued as rs1054963355, COSV67998466; called by muse, mutect2, varscan2
- KIZ | c.1248T>C p.A416= | Silent (SNP) | VAF 27/164 reads (16%) | called by muse, mutect2, varscan2
- KLHL34 | c.693C>T p.D231= | Silent (SNP) | VAF 68/177 reads (38%) | catalogued as rs981857318, COSV65278721; called by muse, mutect2, varscan2
- KRT39 | c.315G>A p.E105= | Silent (SNP) | VAF 112/281 reads (40%) | catalogued as COSV100842175; called by muse, mutect2, varscan2
- LRWD1 | c.1596C>G p.G532= | Silent (SNP) | VAF 45/87 reads (52%) | catalogued as rs1195603578; called by muse, mutect2, varscan2
- LTBP2 | c.2856C>T p.Y952= | Silent (SNP) | VAF 254/678 reads (37%) | called by muse, mutect2, varscan2
- LZTR1 | c.1425G>A p.T475= | Silent (SNP) | VAF 40/248 reads (16%) | catalogued as rs140414846; called by muse, mutect2, varscan2
- MAP2 | c.1566C>T p.T522= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs1202899945, COSV52286814; called by muse, mutect2, varscan2
- MAST4 | c.4398C>T p.H1466= (on ENST00000403625 / NM_001164664.2; = p.H1277= on NM_015183.3) | Silent (SNP) | VAF 98/268 reads (37%) | called by muse, mutect2, varscan2
- MC3R | c.762C>T p.C254= | Silent (SNP) | VAF 9/163 reads (6%) | catalogued as COSV54765196; called by muse, mutect2
- MS4A15 | c.297C>T p.H99= (on ENST00000405633 / NM_001098835.2; = p.H6= on NM_152717.3) | Silent (SNP) | VAF 40/135 reads (30%) | called by muse, mutect2, varscan2
- NFAT5 | c.1680T>C p.S560= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as rs1031086836; called by muse, mutect2, varscan2
- NKX2-5 | c.300C>T p.P100= | Silent (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- NLGN2 | c.144C>T p.Y48= | Silent (SNP) | VAF 52/338 reads (15%) | catalogued as rs750428123; called by muse, mutect2, varscan2
- NPAS3 | c.2076G>A p.P692= (on ENST00000356141 / NM_001164749.2; = p.P660= on NM_022123.3) | Silent (SNP) | VAF 56/175 reads (32%) | catalogued as rs1295093051, COSV60840889; called by muse, mutect2, varscan2
- NR4A2 | c.1119C>T p.V373= | Silent (SNP) | VAF 205/497 reads (41%) | catalogued as COSV59894390; called by muse, mutect2, varscan2
- OR2V2 | c.63C>T p.H21= | Silent (SNP) | VAF 67/197 reads (34%) | called by muse, mutect2, varscan2
- OTOF | c.5247C>T p.D1749= (on ENST00000272371 / NM_194248.3; = p.D982= on NM_004802.4) | Silent (SNP) | VAF 144/421 reads (34%) | catalogued as rs1340855486, COSV55505013; called by muse, varscan2
- OXR1 | c.1767T>C p.H589= (on ENST00000442977 / NM_001198532.1; = p.H588= on NM_018002.3) | Silent (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- PAK6 | c.141G>A p.L47= | Silent (SNP) | VAF 88/269 reads (33%) | called by muse, mutect2, varscan2
- PAOX | c.1116C>A p.A372= | Silent (SNP) | VAF 53/193 reads (27%) | catalogued as COSV53370990, COSV53372538; called by muse, mutect2, varscan2
- PCDH17 | c.1518C>T p.T506= | Silent (SNP) | VAF 119/372 reads (32%) | called by muse, mutect2, varscan2
- PCDHB10 | c.1665C>T p.N555= | Silent (SNP) | VAF 124/465 reads (27%) | called by muse, mutect2, varscan2
- PHF23 | c.366C>A p.P122= | Silent (SNP) | VAF 84/237 reads (35%) | catalogued as COSV50038138; called by muse, mutect2, varscan2
- PIRT | c.186C>T p.G62= | Silent (SNP) | VAF 58/150 reads (39%) | catalogued as rs555559126, COSV74119824; called by muse, mutect2, varscan2
- PKD2 | c.180G>A p.R60= | Silent (SNP) | VAF 43/98 reads (44%) | catalogued as rs1263674695; ClinVar: likely benign; called by muse, varscan2
- PLEC | c.12642C>T p.N4214= (on ENST00000322810 / NM_201380.4; = p.N4104= on NM_000445.5) | Silent (SNP) | VAF 208/593 reads (35%) | catalogued as rs140538836, COSV59653873; called by muse, mutect2, varscan2
- PLXNA1 | c.2322C>T p.Y774= | Silent (SNP) | VAF 134/320 reads (42%) | catalogued as rs147176760; called by muse, mutect2, varscan2
- POPDC2 | c.789C>T p.R263= | Silent (SNP) | VAF 133/324 reads (41%) | catalogued as rs1283131215; called by muse, mutect2, varscan2
- PPP1R12B | c.960G>A p.E320= | Silent (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- PSEN2 | c.771C>T p.G257= | Silent (SNP) | VAF 73/328 reads (22%) | catalogued as rs7539017, COSV60916600; called by muse, mutect2, varscan2
- PTCH1 | c.3360G>A p.E1120= | Silent (SNP) | VAF 173/445 reads (39%) | catalogued as rs1554690458; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTPN18 | c.1146C>T p.S382= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- RALBP1 | c.900G>A p.V300= | Silent (SNP) | VAF 58/183 reads (32%) | called by muse, mutect2, varscan2
- RALY | c.468G>A p.R156= (on ENST00000246194 / NM_016732.3; = p.R140= on NM_007367.4) | Silent (SNP) | VAF 81/239 reads (34%) | called by muse, mutect2, varscan2
- RBM15 | c.1221G>A p.R407= | Silent (SNP) | VAF 77/217 reads (35%) | catalogued as rs777680641; called by muse, mutect2, varscan2
- RPS10-NUDT3 | c.120G>A p.V40= | Silent (SNP) | VAF 25/178 reads (14%) | called by muse, mutect2, varscan2
- SETBP1 | c.819G>A p.T273= | Silent (SNP) | VAF 112/333 reads (34%) | catalogued as rs772700161, COSV56336632; called by muse, mutect2, varscan2
- SETBP1 | c.1431A>G p.S477= | Silent (SNP) | VAF 202/576 reads (35%) | called by muse, varscan2
- SLC38A3 | c.1116C>T p.A372= | Silent (SNP) | VAF 22/177 reads (12%) | catalogued as rs776407403; called by muse, mutect2, varscan2
- SLC39A13 | c.567C>T p.A189= | Silent (SNP) | VAF 75/595 reads (13%) | catalogued as rs774704127, COSV61521040; called by muse, mutect2, varscan2
- SLC4A7 | c.3234G>A p.P1078= | Silent (SNP) | VAF 42/160 reads (26%) | catalogued as rs747613260, COSV55403551; called by muse, mutect2, varscan2
- SLC5A9 | c.651G>A p.T217= | Silent (SNP) | VAF 68/238 reads (29%) | catalogued as rs61730938, COSV52581784, COSV99361310; called by muse, mutect2, varscan2
- SNAP23 | c.255C>T p.C85= | Silent (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- SORBS1 | c.1173A>T p.S391= (on ENST00000361941 / NM_001034954.2; = p.S227= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 43/85 reads (51%) | called by muse, mutect2, varscan2
- SPEG | c.3678C>T p.H1226= | Silent (SNP) | VAF 117/294 reads (40%) | catalogued as rs1388099213; called by muse, mutect2, varscan2
- SSTR4 | c.378C>T p.D126= | Silent (SNP) | VAF 42/105 reads (40%) | catalogued as rs770914493, COSV54796826; called by muse, mutect2, varscan2
- TAPBPL | c.685C>T p.L229= | Silent (SNP) | VAF 136/393 reads (35%) | catalogued as rs1161833645; called by muse, mutect2, varscan2
- TECTA | c.285C>T p.F95= | Silent (SNP) | VAF 97/248 reads (39%) | catalogued as rs775584376, COSV50817729; called by muse, mutect2, varscan2
- TEX38 | c.216A>C p.R72= | Silent (SNP) | VAF 70/172 reads (41%) | called by muse, mutect2, varscan2
- TFRC | c.2094A>G p.R698= | Silent (SNP) | VAF 103/274 reads (38%) | called by muse, mutect2, varscan2
- THEMIS2 | c.1866G>A p.R622= | Silent (SNP) | VAF 45/121 reads (37%) | called by muse, mutect2, varscan2
- TRAPPC12 | c.762C>T p.P254= | Silent (SNP) | VAF 76/205 reads (37%) | catalogued as rs774631193; called by muse, mutect2, varscan2
- TRNAU1AP | c.849C>A p.I283= | Silent (SNP) | VAF 59/138 reads (43%) | called by muse, mutect2, varscan2
- TTN | c.73296A>G p.V24432= (on ENST00000591111; = p.V17008= on NM_003319.4) | Silent (SNP) | VAF 57/180 reads (32%) | catalogued as rs761647014; called by muse, mutect2, varscan2
- UPB1 | c.852C>T p.C284= | Silent (SNP) | VAF 222/568 reads (39%) | catalogued as rs781196303, COSV58116158; called by muse, mutect2, varscan2
- USH2A | c.8826C>T p.D2942= | Silent (SNP) | VAF 50/338 reads (15%) | catalogued as rs775823422; called by muse, mutect2, varscan2
- VEGFD | c.438C>T p.C146= | Silent (SNP) | VAF 74/179 reads (41%) | called by muse, mutect2, varscan2
- VGLL2 | c.666G>A p.P222= | Silent (SNP) | VAF 140/399 reads (35%) | called by muse, mutect2, varscan2
- WDR90 | c.2143C>T p.L715= | Silent (SNP) | VAF 133/401 reads (33%) | called by muse, mutect2, varscan2
- ZFYVE26 | c.408T>C p.P136= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as rs186059110; called by muse, mutect2
- ZNF239 | c.303C>T p.S101= | Silent (SNP) | VAF 19/135 reads (14%) | catalogued as rs1326110759; called by muse, mutect2, varscan2
- ZNF544 | c.1680C>T p.N560= | Silent (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- ZNF644 | c.1824G>A p.L608= | Silent (SNP) | VAF 38/100 reads (38%) | called by muse, mutect2, varscan2
- ZNF850 | c.723T>C p.I241= | Silent (SNP) | VAF 26/86 reads (30%) | called by muse, mutect2, varscan2
- AC107023.1 | chr12:40444462 G>A | 5'Flank (SNP) | VAF 46/123 reads (37%) | called by muse, mutect2, varscan2
- AC109583.1 | c.-542-14097C>T | Intron (SNP) | VAF 102/226 reads (45%) | catalogued as rs1190788629; called by muse, mutect2, varscan2
- ADAM1A | n.1368C>T | RNA (SNP) | VAF 91/268 reads (34%) | called by muse, mutect2, varscan2
- AK9 | c.1254+19_1254+22del | Intron (DEL) | VAF 19/50 reads (38%) | catalogued as rs770626634; called by mutect2, varscan2*
- AKT2 | c.639+148G>A | Intron (SNP) | VAF 25/358 reads (7%) | catalogued as rs752039870; called by muse, mutect2
- ANXA8 | c.*181C>T | 3'UTR (SNP) | VAF 210/1064 reads (20%) | called by muse, varscan2
- ARHGEF25 | chr12:57620943 G>A | 3'Flank (SNP) | VAF 156/416 reads (38%) | called by muse, mutect2, varscan2
- ARHGEF28 | c.4948+11575C>A | Intron (SNP) | VAF 35/142 reads (25%) | called by muse, mutect2, varscan2
- ARL13B | c.130+613del | Intron (DEL) | VAF 36/84 reads (43%) | called by mutect2, pindel, varscan2
- B3GALNT2 | c.113-1407G>A | Intron (SNP) | VAF 6/46 reads (13%) | catalogued as rs1383985581; called by muse, mutect2, varscan2
- CACNB1 | c.1332+23G>A | Intron (SNP) | VAF 78/218 reads (36%) | called by muse, mutect2, varscan2
- CCDC162P | n.2516T>C | RNA (SNP) | VAF 16/372 reads (4%) | catalogued as rs936093896; called by muse, mutect2
- CD300LD | chr17:74592352 del T | 5'Flank (DEL) | VAF 15/150 reads (10%) | called by mutect2, pindel, varscan2
- CDK5RAP3 | chr17:47971080 C>A | 5'Flank (SNP) | VAF 52/118 reads (44%) | called by muse, mutect2, varscan2
- CFAP52 | c.71-1461G>A | Intron (SNP) | VAF 29/86 reads (34%) | catalogued as rs867168009; called by muse, mutect2, varscan2
- COL4A1 | c.4462+45T>C | Intron (SNP) | VAF 27/189 reads (14%) | called by muse, mutect2, varscan2
- COL5A1 | c.3367-41G>A | Intron (SNP) | VAF 10/298 reads (3%) | called by muse, mutect2
- COQ8A | c.*34A>T | 3'UTR (SNP) | VAF 84/459 reads (18%) | called by muse, mutect2, varscan2
- CTDSP1 | c.67+557G>A | Intron (SNP) | VAF 95/277 reads (34%) | catalogued as rs910857141; called by muse, mutect2, varscan2
- DDX11 | c.638+900G>A | Intron (SNP) | VAF 139/447 reads (31%) | catalogued as rs1215835829; called by muse, mutect2, varscan2
- DOK6 | c.-36C>T | 5'UTR (SNP) | VAF 106/292 reads (36%) | catalogued as rs1218006178, COSV101235037; called by muse, mutect2, varscan2
- EGFL6 | c.*50del | 3'UTR (DEL) | VAF 20/68 reads (29%) | catalogued as rs1446348498; called by mutect2, pindel
- EMC10 | c.679-266C>G | Intron (SNP) | VAF 53/136 reads (39%) | catalogued as rs779918120, COSV58541974; called by muse, mutect2, varscan2
- ENAH | c.803-282del | Intron (DEL) | VAF 31/214 reads (14%) | called by mutect2, pindel, varscan2
- FAM181A | c.100-576C>T | Intron (SNP) | VAF 48/151 reads (32%) | called by muse, mutect2, varscan2
- FAS | c.*589C>T | 3'UTR (SNP) | VAF 30/161 reads (19%) | called by muse, mutect2, varscan2
- FMO6P | n.1375G>T | RNA (SNP) | VAF 32/437 reads (7%) | catalogued as rs1462308165; called by muse, mutect2
- GLYCTK | c.-47G>C | 5'UTR (SNP) | VAF 49/150 reads (33%) | called by muse, mutect2, varscan2
- GNAS | c.2068+240C>T | Intron (SNP) | VAF 76/243 reads (31%) | catalogued as rs967732544; called by muse, mutect2, varscan2
- HDAC4 | c.2855-16C>T | Intron (SNP) | VAF 9/121 reads (7%) | catalogued as COSV61868142; called by muse, mutect2
- HEXD | c.*44del | 3'UTR (DEL) | VAF 93/276 reads (34%) | catalogued as rs751615819; called by mutect2, pindel, varscan2
- JAKMIP2 | c.2413-2775T>C | Intron (SNP) | VAF 66/169 reads (39%) | called by muse, mutect2, varscan2
- KCNC3 | c.*1385C>T | 3'UTR (SNP) | VAF 20/77 reads (26%) | called by muse, mutect2, varscan2
- KDM4C | c.2994+116del | Intron (DEL) | VAF 52/134 reads (39%) | catalogued as COSV67183745; called by mutect2, varscan2
- L3MBTL1 | c.1193-30C>T | Intron (SNP) | VAF 68/257 reads (26%) | catalogued as rs374464014; called by muse, mutect2, varscan2
- LRRC27 | chr10:132331751 ins C | 5'Flank (INS) | VAF 19/171 reads (11%) | called by mutect2, pindel, varscan2
- LRRC8D | c.-141C>T | 5'UTR (SNP) | VAF 48/168 reads (29%) | called by muse, mutect2, varscan2
- MAPRE3 | c.267+106G>A | Intron (SNP) | VAF 18/51 reads (35%) | catalogued as rs767804788; called by muse, mutect2, varscan2
- MDFIC | c.-7G>A | 5'UTR (SNP) | VAF 79/200 reads (40%) | catalogued as rs930922489; called by muse, mutect2, varscan2
- MGAT4B | c.720-10C>T | Intron (SNP) | VAF 44/282 reads (16%) | catalogued as rs768415930; called by muse, mutect2, varscan2
- MS4A6A | c.651+10C>T | Intron (SNP) | VAF 86/248 reads (35%) | called by muse, mutect2, varscan2
- MUCL3 | c.946+868A>G | Intron (SNP) | VAF 82/339 reads (24%) | catalogued as rs1305952989, COSV58516256; called by muse, varscan2
- NAPA | c.561+148del | Intron (DEL) | VAF 42/112 reads (38%) | catalogued as rs1349876274; called by mutect2, varscan2
- NEK7 | c.198+3306del | Intron (DEL) | VAF 11/49 reads (22%) | catalogued as rs749732874; called by mutect2, pindel
- NLRC5 | c.4154+205G>T | Intron (SNP) | VAF 47/136 reads (35%) | catalogued as rs1295311548; called by muse, varscan2
- NRIP3 | c.*612G>A | 3'UTR (SNP) | VAF 22/65 reads (34%) | catalogued as rs1339089593, COSV100487129; called by muse, mutect2, varscan2
- NVL | c.285-15C>A | Intron (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- OGFOD1 | c.301-20del | Intron (DEL) | VAF 31/90 reads (34%) | catalogued as rs771823733; called by mutect2, varscan2
- OR7A2P | n.362G>A | RNA (SNP) | VAF 28/211 reads (13%) | catalogued as rs528570028; called by muse, mutect2, varscan2
- PADI1 | c.*96dup | 3'UTR (INS) | VAF 200/596 reads (34%) | called by mutect2, pindel, varscan2
- PCSK4 | c.1391+15C>T | Intron (SNP) | VAF 50/139 reads (36%) | catalogued as rs539574874; called by muse, mutect2, varscan2
- PHYKPL | c.59+17C>T | Intron (SNP) | VAF 53/121 reads (44%) | catalogued as rs749198645; called by muse, mutect2, varscan2
- PI4KAP2 | n.2831C>A | RNA (SNP) | VAF 80/225 reads (36%) | called by muse, varscan2
- PITRM1 | c.2646-904C>T | Intron (SNP) | VAF 36/126 reads (29%) | catalogued as rs919528512; called by muse, mutect2, varscan2
- PLEKHD1 | c.243+99C>T | Intron (SNP) | VAF 21/42 reads (50%) | called by muse, mutect2, varscan2
- POLM | c.714+75C>A | Intron (SNP) | VAF 44/116 reads (38%) | called by muse, varscan2
- POPDC2 | c.1009+84del | Intron (DEL) | VAF 13/72 reads (18%) | called by mutect2, pindel, varscan2
- POU2F2 | c.303+365G>T | Intron (SNP) | VAF 26/148 reads (18%) | catalogued as rs368244459; called by muse, varscan2
- PPFIA1 | c.2163+1522del | Intron (DEL) | VAF 20/157 reads (13%) | called by mutect2, pindel, varscan2
- PRKCB | c.-5G>A | 5'UTR (SNP) | VAF 100/248 reads (40%) | called by muse, mutect2, varscan2
- PRRC2C | c.8199+1071G>A | Intron (SNP) | VAF 85/415 reads (20%) | called by muse, mutect2, varscan2
- PUS10 | c.126+907C>T | Intron (SNP) | VAF 31/90 reads (34%) | called by muse, mutect2, varscan2
- RAB26 | c.307-380T>G | Intron (SNP) | VAF 43/143 reads (30%) | called by muse, mutect2, varscan2
- RNF14 | chr5:141991892 G>A | 3'Flank (SNP) | VAF 49/174 reads (28%) | called by muse, mutect2, varscan2
- RNF220 | c.1630-10C>G | Intron (SNP) | VAF 51/315 reads (16%) | called by muse, mutect2, varscan2
- RPL28 | c.205+160_205+162del | Intron (DEL) | VAF 34/112 reads (30%) | catalogued as rs750063282; called by mutect2, pindel, varscan2
- SCN4B | c.*317G>A | 3'UTR (SNP) | VAF 190/567 reads (34%) | catalogued as rs1431822176; called by muse, mutect2, varscan2
- SLAMF8 | chr1:159837959 C>T | 3'Flank (SNP) | VAF 79/452 reads (17%) | called by muse, mutect2, varscan2
- SNAP47 | c.1249-4721G>A | Intron (SNP) | VAF 63/321 reads (20%) | catalogued as rs566590122; called by muse, mutect2, varscan2
- SPATA33 | c.34+158G>T | Intron (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- SRD5A3 | c.-33dup | 5'UTR (INS) | VAF 36/130 reads (28%) | called by mutect2, pindel
- STAB1 | c.4364-40del | Intron (DEL) | VAF 42/99 reads (42%) | called by mutect2, pindel, varscan2
- TP53AIP1 | c.141+48C>A | Intron (SNP) | VAF 47/224 reads (21%) | catalogued as COSV101513087; called by muse, mutect2, varscan2
- TPRXL | n.752C>T | RNA (SNP) | VAF 29/236 reads (12%) | catalogued as rs192562800; called by muse, varscan2
- UBR2 | c.1281+157G>A | Intron (SNP) | VAF 38/101 reads (38%) | catalogued as rs978399522; called by muse, mutect2, varscan2
- ZDHHC23 | c.1217-20del | Intron (DEL) | VAF 15/37 reads (41%) | catalogued as rs767083235; called by mutect2, varscan2
- ZFHX4 | c.3093+97del | Intron (DEL) | VAF 18/95 reads (19%) | catalogued as rs751858242; called by mutect2, varscan2
- ZNF252P | n.245+3153del | Intron (DEL) | VAF 7/23 reads (30%) | called by mutect2, pindel, varscan2
- ZNF420 | c.*1105A>G | 3'UTR (SNP) | VAF 20/145 reads (14%) | catalogued as rs888810436; called by muse, mutect2, varscan2
- ZRANB3 | c.1206+399del | Intron (DEL) | VAF 21/81 reads (26%) | called by mutect2, pindel, varscan2
